FM case AD14921 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and unspecified major salivary glands.
https://portal.gdc.cancer.gov/cases/eb3b90f6-f0f6-41da-9f85-44ccf2e9771e

Male, 62.7 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the major salivary gland; specimen biopsied or resected from the head, face or neck. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Tumor.
